Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9J0, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9J0-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Final Diagnosis

- A. LYMPH NODE, HEPATIC ARTERY, BIOPSY:
One lymph node, negative for metastatic carcinoma (0/1).
- B. PORTION OF HEAD OF PANCREAS, PORTION OF DUODENUM, DISTAL STOMACH,
PORTION OF COMMON BILE DUCT, AND GALLBLADDER, STANDARD
PANCREATODUODENECTOMY:
Pancreatic ductal adenocarcinoma, moderately differentiated, measuring 4.0 cm, extending
into Ampulla, duodenum and peripancreatic tissue.
Carcinoma approaches to 0.75 mm of the posterior surface.
Portal vein groove and superior mesenteric artery are negative for carcinoma.
The common bile duct margin is negative for dysplasia and carcinoma.
Gallbladder with chronic cholecystitis.
Adjacent pancreatic parenchyma with PanIN-3, see comment.
Metastatic carcinoma to 5 of 14 peripancreatic lymph nodes (5/14).
Perineural, lymphovascular and large vessel invasion identified.
- C. PANCREAS, NEW PANCREATIC MARGIN, RESECTION:
Low-grade dysplasia identified.
Negative for carcinoma.

I, _____ the attending pathologist, personally reviewed all
slides and / or materials and rendered the final diagnosis. Electronically
Signed Out by _____

Comment

Sections through the Ampulla show apancreatic ductal adenocarcinoma secondarily involving the Ampulla and common bile duct. A precursor lesion for the carcinoma is not identified in the Ampulla, duodenum or bile duct. The carcinoma, however, is centered on the main pancreatic duct. The adjacent pancreatic parenchyma shows PanIN 3. These findings support the interpretation of this as a pancreatic ductal primary, rather than an Ampullary or common bile duct primary.

Ancillary Testing

Immunohistochemical stains with appropriate controls were performed on block B9. These results show strong and diffuse expression for MUC-1, and no expression for MUC-2 and CDX2. These results are consistent with a pancreatobiliary phenotype.

Key Pathological Findings

SPECIMEN:

Head of pancreas
Duodenum
Stomach
Common bile duct
Gallbladder

ICD O-3
Adenocarcinoma, duct NOS
Site: Pancreas head C25.0
JED 4/16/14

[page 2 of 4]
PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE:

Greatest dimension of solid component: 4.0 cm

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades ampulla of Vater or sphincter of Oddi

Tumor invades duodenal wall

Tumor invades peripancreatic soft tissues

Tumor invades retroperitoneal soft tissue

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 0.75 mm

Specified margin: posterior surface

Margins uninvolved by carcinoma in situ

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

No prior treatment

LYMPH-VASCULAR INVASION:

Present

PERINEURAL INVASION:

Present

TNM DESCRIPTORS:

Not applicable

PRIMARY TUMOR (pT):

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 15

Number involved: 5

DISTANT METASTASIS (pM):

pM0: No Distant metastasis

ADDITIONAL PATHOLOGIC FINDINGS:

Pancreatic intraepithelial neoplasia (highest grade: PanIN 3)

ANCILLARY STUDIES

Specimen(s) Received

- A HEPATIC ARTERY LYMPH NODES FS
- B WHIPPLE SPECIMEN FS
- C NEW PANCREATIC MARGIN FS

Clinical History

NOT GIVEN.

[page 3 of 4]
Preoperative Diagnosis

AMPULLARY CA.

Intraoperative Consultation

FSA1. HEPATIC ARTERY LYMPH NODE FROZEN SECTION:
Negative for carcinoma.

FSB1. WHIPPLE, COMMON BILE DUCT MARGIN:
Negative.

FSC1. NEW PANCREATIC MARGIN:
Negative.

Comment: These frozen section diagnoses/results were communicated to and acknowledged by Dr.

I, _____, have performed the intraoperative consultations and issued the above diagnosis.

Gross Description

A. Specimen A is received fresh for frozen section analysis labeled "hepatic artery lymph node." The specimen consists of a 2.0 x 1.5 x 0.5-cm, firm gray-brown irregular lymph node which is bisected and entirely submitted for frozen section as FSA1.

B. Specimen B is received fresh for frozen section analysis labeled "bile duct, gallbladder portion of pancreas duodenum and distal stomach." The specimen consists of a portion of the pancreas (4.5 x 3.0 x 2.0 cm), duodenum (8.0 cm in length), gallbladder (10.0 x 3.0 x 3.0 cm). No distal stomach is grossly appreciated. The portal vein groove is marked with blue ink, superior mesenteric artery margin yellow ink, and retroperitoneal surface exterior green ink. The pancreatic duct is probe-patent for approximately 2.0 cm and is grossly occluded by firm indurated gray-tan mass (4.0 x 3.0 x 2.0 cm). Grossly the mass appears to be directly subjacent to the common bile duct and grossly involving the Ampulla. The remaining pancreatic parenchyma consists of a yellow lobulated grossly unremarkable tissue. The common bile duct is probe-patent but does grossly appear to be somewhat dilated. The remainder of the duodenal mucosa exhibits normal intestinal folds. No other nodules or polyps are grossly appreciated. The serosa of the gallbladder is green-yellow and smooth. On opening, there is a moderate amount of green viscous bile. No calculi grossly appreciated. The mucosal surface of the gallbladder is green-yellow and velvet-like. No stomach is grossly appreciated. A representative section of the tumor is submitted to Tissue Procurement Laboratory. A representative frozen section is taken and submitted as:

FSB1: Tangential common bile duct margin of resection

Permanent representative sections are submitted as:

B2: Portal vein groove perpendicularly sectioned
B3: Superior mesenteric artery tangentially removed and perpendicularly sectioned.
B4: Retroperitoneal surface perpendicularly sectioned.
B5: Tangential pancreatic margin of resection

[page 4 of 4]
B6: Proximal duodenum/distal stomach
B7: Distal duodenum
B8-B9: Tumor showing its relationship to pancreas, Ampulla of Vater, and duodenum
B10: Cross section of common bile duct showing relationship to tumor
B11-B13: Random representative sections of tumor showing relationship to adjacent tissue
B14: Longitudinal section pancreatic duct
B15: Cross section pancreatic duct and adjacent lymph node
B16: Grossly unremarkable duodenal mucosa
B17: Gallbladder
B18-B19: Unsectioned lymph nodes isolated at pancreas
B20-B21: Entire adipose tissue
B22-B25: Remainder of Ampulla

C. Specimen C is received fresh for frozen section analysis labeled "new pancreatic margin, new margin up." The specimen consists of a 3.0 x 1.5 x 0.3-cm, firm yellow-tan lobulated fragment of pancreas. The margin of resection is removed tangentially and entirely submitted on frozen section as FSC1.

IIFAA Discrepancy		☒

Source: NCI Genomic Data Commons file e244006b-11fa-4eba-9af8-c0559f3c84ea (TCGA-3A-A9J0.0FEC454A-9BE2-4538-A74B-4BE531410B6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).